CCDI case PBCHYB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ec85a5cc-da50-45c2-954a-bf51316281ec

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 7.2 years (2,639 days).

Biospecimens (4 samples)
- Samples 0DSEKL, 0DSF01 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSEYZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSMXX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
